Somatic mutation profile of tumor specimen TARGET-50-CAAAAP-01A (aliquot TARGET-50-CAAAAP-01A-01D) from TARGET case TARGET-50-CAAAAP, project TARGET-WT (High-Risk Wilms Tumor). Sex at birth: male; Vital status: Alive; Primary diagnosis: Wilms tumor; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 2.3 years (824 days).
Specimen TARGET-50-CAAAAP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7bc7c843-5a6a-47e0-9bdb-3adef86cfc25.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-50-CAAAAP-10A (Blood Derived Normal), aliquot TARGET-50-CAAAAP-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7c05976d-209e-4e6b-bb8b-8054bc9fd830

The open-access MAF lists 6 somatic variants for this specimen: 6 protein-altering or splice-affecting.
By variant classification: Missense Mutation 6.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CHD6 | c.3626C>T p.P1209L | Missense Mutation (SNP) | VAF 69/139 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.342); catalogued as COSV58554413; called by muse, mutect2
- NFATC2 | c.2708C>T p.T903I | Missense Mutation (SNP) | VAF 66/159 reads (42%) | SIFT tolerated (0.39); PolyPhen benign (0.223); catalogued as COSV65359555; called by mutect2, varscan2
- SMCO1 | c.268C>T p.R90C | Missense Mutation (SNP) | VAF 55/134 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs374608743; called by muse, mutect2, varscan2
- TSTD2 | c.982G>A p.D328N | Missense Mutation (SNP) | VAF 41/138 reads (30%) | SIFT tolerated (0.39); PolyPhen benign (0.063); catalogued as rs1191452659; called by muse, mutect2, varscan2
- ZKSCAN4 | c.540A>T p.E180D | Missense Mutation (SNP) | VAF 108/237 reads (46%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.918); catalogued as COSV66023108; called by muse, mutect2, varscan2
- CDH5 | c.1114T>C p.F372L | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); called by muse, varscan2
